Somatic mutation profile of tumor specimen TCGA-KN-8430-01A (aliquot TCGA-KN-8430-01A-11D-2310-10) from TCGA case TCGA-KN-8430, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 75.2 years (27,467 days).
Specimen TCGA-KN-8430-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea025b4a-b85e-49ea-8805-2de6b15e1ff1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8430-11A (Solid Tissue Normal), aliquot TCGA-KN-8430-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f116ebe-8320-4c1b-a4b6-efad3b2459b7

The open-access MAF lists 34 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Frame Shift Ins 1, Splice Region 1, Frame Shift Del 1, Intron 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN1B | c.476-1G>C p.X159_splice | Splice Site (SNP) | VAF 8/80 reads (10%) | hotspot (GDC flag); catalogued as COSV57430077, COSV57430259; called by muse, mutect2
- FANCD2 | c.2204G>A p.R735Q | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755975980, CM130431, COSV55046363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALLC | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99377618; called by muse, mutect2
- CELSR2 | c.4588G>T p.D1530Y | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54770735; called by muse, mutect2, varscan2
- CLTCL1 | c.4445C>T p.A1482V | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV99594635; called by muse, mutect2, varscan2
- COL20A1 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV100490076; called by muse, mutect2, varscan2
- COL25A1 | c.335G>C p.R112T | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV101211270; called by muse, mutect2
- CRACD | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs758586331, COSV51720199, COSV51733496; called by muse, mutect2, varscan2
- FAT3 | c.9423T>A p.Y3141* | Nonsense Mutation (SNP) | VAF 12/164 reads (7%) | catalogued as COSV53157067, COSV99963151; called by muse, mutect2
- FKTN | c.120G>T p.L40F | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV99795305; called by muse, mutect2
- HERC5 | c.1854C>T p.D618= | Splice Region (SNP) | VAF 122/303 reads (40%) | catalogued as rs369956338; called by muse, mutect2, varscan2
- HPR | c.959A>G p.D320G | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT tolerated (0.87); PolyPhen probably damaging (1); catalogued as COSV99930823; called by muse, mutect2
- KIAA1109 | c.12716C>T p.T4239M | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs755406183, COSV52681048; called by muse, mutect2, varscan2
- KREMEN1 | c.362G>T p.G121V (on ENST00000407188; = p.G123V on NM_032045.5) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768929560, COSV100588605; called by muse, mutect2, varscan2
- MACF1 | c.6970A>T p.S2324C | Missense Mutation (SNP) | VAF 28/97 reads (29%) | catalogued as COSV99242258; called by muse, mutect2, varscan2
- MYO7A | c.5739C>G p.D1913E | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.992); catalogued as COSV101289071; called by muse, mutect2, varscan2
- NHSL1 | c.2257A>G p.T753A | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV100606655; called by muse, mutect2
- PBRM1 | c.2296G>T p.D766Y | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV99967796; called by muse, mutect2
- SLC26A7 | c.1514T>C p.I505T | Missense Mutation (SNP) | VAF 89/221 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV99402863; called by muse, mutect2, varscan2
- STAG1 | c.3052G>A p.D1018N | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99364721; called by muse, mutect2, varscan2
- TRRAP | c.11266G>A p.A3756T (on ENST00000359863 / NM_001244580.1; = p.A3727T on NM_003496.3) | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs145619183; called by muse, mutect2, varscan2
- TSHZ3 | c.2252T>C p.F751S | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.979); catalogued as COSV99550917; called by muse, mutect2, varscan2
- WEE1 | c.1852A>T p.M618L | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100219622; called by muse, mutect2, varscan2
- ZFP30 | c.294G>T p.M98I | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63622490, COSV63623171; called by muse, mutect2, varscan2
- ZNF319 | c.199C>G p.P67A | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99540026; called by muse, mutect2, varscan2
- C3orf20 | c.27dup p.L10Ifs*39 | Frame Shift Ins (INS) | VAF 14/76 reads (18%) | called by mutect2, pindel, varscan2
- POTEJ | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 164/329 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- ZFR | c.100_107del p.S34Gfs*10 | Frame Shift Del (DEL) | VAF 14/105 reads (13%) | called by mutect2, pindel, varscan2
- AARD | c.456G>A p.A152= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs748488380, COSV65599677; called by muse, mutect2, varscan2
- AJAP1 | c.816G>T p.L272= | Silent (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- FAM71E2 | c.1686C>A p.G562= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs537757899, COSV100427707; called by muse, mutect2, varscan2
- GAD1 | c.1194A>C p.S398= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV100827909; called by muse, mutect2, varscan2
- GPR148 | c.210G>A p.L70= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV99998532; called by muse, mutect2, varscan2
- ACTB | c.363+102G>A | Intron (SNP) | VAF 68/160 reads (43%) | called by muse, mutect2, varscan2
